Gene-level copy-number profile of tumor specimen CUPP-B38L-TTM1-A from CCG case CUPP-B38L, project CCG-CUPP: Center for Cancer Genomics (CCG) Cancers of Unknown Primary Project (CUPP). Sex at birth: male; Vital status: Dead; Primary diagnosis: Adenocarcinoma, metastatic, NOS; Tissue or organ of origin: Unknown primary site; AJCC pathologic stage: Stage III; Age at diagnosis: 59.9 years (21,864 days).
Specimen CUPP-B38L-TTM1-A: Sample type: Metastatic; Tissue type: Tumor; Tumor descriptor: Metastatic; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 47dd9dd5-6a1d-49f0-ae22-5b4bbc86b930.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator CUPP-B38L-NB1-A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,714 have no estimate.
https://portal.gdc.cancer.gov/files/2fa3c9f1-788f-4611-bb35-d7153d82d179

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 49; copy number 1: 12,423; copy number 2: 39,689; copy number 3: 6,472; copy number 4: 151; copy number 5: 58; copy number 6: 5; copy number 8: 3; copy number 10: 36; copy number 11: 1; copy number 12: 1; copy number 14: 17; copy number 18: 2; copy number 26: 1; copy number 32: 1.

Homozygous deletions (total copy number 0; autosomes only): 49 genes in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr9:21,278,050–23,898,054, 49 genes: IFNA22P, IFNA5, IFNA20P, KLHL9, IFNA6, IFNA13, IFNA2, AL353732.1, IFNA11P, IFNA12P, IFNA8, AL353732.2, IFNWP2, IFNA1, MIR31HG, IFNWP19, IFNE, MIR31, SNORD39, H3P30, KHSRPP1, RN7SL151P, MTAP, AL359922.1, TUBB8P1, AL359922.2, AL359922.3, ERVFRD-3, CDKN2A-DT, CDKN2A, CDKN2B-AS1, AL449423.1, CDKN2B, UBA52P6, AL354709.1, AL354709.2, AL157937.1, DMRTA1, LINC01239, AL391117.1, CLIC4P1, AC017067.1, AL445623.2, SUMO2P2, AL445623.1, NOP56P2, ELAVL2, AL365204.1, AL365204.2.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 124 genes in 12 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr4:49,096–50,124, 1 gene, copy number 5: BNIP3P41.
- chr9:64,621,560–64,765,535, 5 genes, copy number 6: AQP7P2, AL445665.1, BMS1P11, AL359955.2, IGKV1OR-2.
- chr9:64,817,870–64,836,341, 1 gene, copy number 5: AL359955.1.
- chr14:18,333,726–18,412,264, 3 genes, copy number 8: CR383658.1, RNU6-458P, CR383658.2.
- chr14:21,941,128–22,014,964, 10 genes, copy number 5: TRAV9-2, TRAV15, AC245505.1, TRAV12-3, TRAV8-6, TRAV16, TRAV17, TRAV18, TRAV19, AC245505.2.
- chr14:22,066,016–22,494,883, 54 genes, copy number 5–14: AC245505.3, TRAV22, TRAV23DV6, TRDV1, TRAV24, TRAV25, TRAV26-1, TRAV8-7, TRAV27, TRAV28, TRAV29DV5, TRAV30, TRAV31, TRAV32, TRAV33, AC244502.1, TRAV26-2, TRAV34, TRAV35, TRAV36DV7, TRAV37, TRAV38-1, TRAV38-2DV8, TRAV39, TRAV40, TRAV41, AC244502.2, AC244502.3, TRDV2, TRDD1, TRDD2, TRDD3, TRDJ1, TRDJ4, TRDJ2, TRDJ3, TRDC, TRDV3, TRAJ61, TRAJ60, TRAJ59, TRAJ58, TRAJ57, TRAJ56, TRAJ55, TRAJ54, TRAJ53, TRAJ52, TRAJ51, TRAJ50, TRAJ47, TRAJ46, TRAJ45, TRAJ44.
- chr14:22,547,506–22,552,156, 1 gene, copy number 10: TRAC.
- chr15:21,298,233–21,946,641, 37 genes, copy number 5 (within-gene range 5–12): AC068446.2, RNU6-1235P, AC060814.4, AC060814.3, LONRF2P4, AC060814.2, CXADRP2, AC060814.1, GRAMD4P6, POTEB3, MIR3118-3, U6, NF1P9, MIR5701-2, AC183088.4, AC183088.2, AC183088.1, LINC02203, AC183088.3, AC135068.6, AC135068.2, AC135068.12, AC135068.11, AC135068.1, AC135068.4, AC135068.5, AC135068.8, AC135068.7, AC135068.9, AC135068.10, AC135068.3, AC134981.1, MIR3118-4, POTEB, RNU6-631P, ZNF519P3, NF1P2.
- chr15:21,980,277–21,981,245, 1 gene, copy number 5: OR11J6P.
- chr21:43,446,601–43,479,534, 3 genes, copy number 18–32: LINC00319, LINC00313, AP001048.1.
- chr21:44,107,373–44,210,114, 2 genes, copy number 11–12 (within-gene range 2–12): PWP2, GATD3A.
- chr22:18,650,023–18,843,399, 6 genes, copy number 5–26: PPP1R26P2, PPP1R26P4, FAM230E, GGT3P, AC008132.2, E2F6P1.

Autosomal genes at a single copy (total copy number 1): 10,263. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
